Somatic mutation profile of tumor specimen TARGET-10-PARASC-09A (aliquot TARGET-10-PARASC-09A-01D) from TARGET case TARGET-10-PARASC, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.5 years (1,994 days).
Specimen TARGET-10-PARASC-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 38a549a5-4f54-4a8c-9ed5-f2ea84cfed27.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARASC-10A (Blood Derived Normal), aliquot TARGET-10-PARASC-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/61b9279b-5c88-44f0-914d-4a25885716f6

The open-access MAF lists 20 somatic variants for this specimen: 12 protein-altering or splice-affecting, 5 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 5, Intron 2, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 17/46 reads (37%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.323); catalogued as rs121434596, CM071907, COSV54736416, COSV54736480, COSV54736793; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA3 | c.1321G>A p.V441I | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.23); PolyPhen benign (0.259); catalogued as rs374138846; called by muse, mutect2, varscan2
- CREBBP | c.4471C>A p.Q1491K | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs201156486, COSV52120333, COSV52125130; called by muse, mutect2, varscan2
- MAGEB16 | c.505G>T p.D169Y | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV67874465; called by muse, mutect2
- NYAP2 | c.670C>T p.R224W | Missense Mutation (SNP) | VAF 32/67 reads (48%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.998); catalogued as rs1272677794, COSV56006238; called by muse, mutect2, varscan2
- SEC14L1 | c.941T>C p.L314P | Missense Mutation (SNP) | VAF 38/66 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs375660465; called by muse, mutect2, varscan2
- AMER3 | c.1276T>C p.F426L | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- POU4F3 | c.299C>G p.P100R | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- PREX2 | c.2162A>G p.K721R | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PRPF8 | c.4783C>G p.Q1595E | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.547); called by muse, mutect2, varscan2
- SYNE1 | c.6476T>C p.I2159T (on ENST00000367255 / NM_182961.4; = p.I2166T on NM_033071.3) | Missense Mutation (SNP) | VAF 33/125 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- USP42 | c.1852G>A p.E618K | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- DPP6 | c.660C>T p.V220= (on ENST00000377770 / NM_001364500.2; = p.V158= on NM_001936.5) | Silent (SNP) | VAF 17/38 reads (45%) | catalogued as rs1344581298; called by muse, mutect2
- HOXB3 | c.969G>A p.P323= | Silent (SNP) | VAF 8/27 reads (30%) | called by muse, mutect2, varscan2
- LRRC53 | c.882G>A p.L294= | Silent (SNP) | VAF 8/18 reads (44%) | called by muse, mutect2, varscan2
- PTPRT | c.3675C>T p.D1225= | Silent (SNP) | VAF 21/55 reads (38%) | catalogued as rs201193836, COSV61959530; called by muse, mutect2, varscan2
- TBC1D26 | c.627G>A p.A209= | Silent (SNP) | VAF 14/37 reads (38%) | catalogued as rs373600282, COSV68610490; called by muse, mutect2, varscan2
- DNAI4 | c.2014-91G>A | Intron (SNP) | VAF 5/14 reads (36%) | called by muse, mutect2, varscan2
- NAPSA | c.468+55A>T | Intron (SNP) | VAF 10/13 reads (77%) | called by muse, mutect2, varscan2
- SCARB2 | chr4:76214259 G>A | 5'Flank (SNP) | VAF 5/12 reads (42%) | called by muse, mutect2
